CGCI case BLGSP-71-17-00357 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ecb32de8-0099-495a-a8a0-c4a1a729b52f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 69.9 years (25,523 days); Year of diagnosis: 2016; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 616 days (1.7 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Supraclavicular lymph nodes; Sites of involvement: Bone marrow / Central nervous system / Gallbladder / Liver / Pancreas, NOS / Kidney, NOS / Mouth.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Supraclavicular.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 616 days (1.7 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 449 [Blood test normal range upper: 246].

Other clinical attributes
- Day 0: Weight: 84.5 kg; Height: 160.2 cm; BMI: 32.9.

Biospecimens (3 samples)
- Sample BLGSP-71-17-00357-01B: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-17-00357-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-17-00357-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt Lymphoma; Extranodal involvment other: Right Floor of Mouth; Days from index date to tumor sample procurement: 1.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 449.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
